Somatic mutation profile of tumor specimen TCGA-61-1910-01A (aliquot TCGA-61-1910-01A-01W-0639-09) from TCGA case TCGA-61-1910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,779 days).
Specimen TCGA-61-1910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9990dd-2c8f-46ce-8e4d-4d26cd2c2543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1910-11A (Solid Tissue Normal), aliquot TCGA-61-1910-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de7d50c-bf51-41b7-8edd-c550bd0bafbb

The open-access MAF lists 115 somatic variants for this specimen: 79 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 34, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 2, Splice Region 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK2 | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV50780881; called by muse, varscan2
- AREL1 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748714324, COSV62665434, COSV62665773; called by muse, mutect2, varscan2
- CCDC15 | c.2119C>T p.Q707* | Nonsense Mutation (SNP) | VAF 15/16 reads (94%) | catalogued as COSV100776978, COSV61080751; called by muse, mutect2, varscan2
- CCDC34 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV60820315; called by muse, mutect2
- CFH | c.467A>T p.K156I | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV62776625; called by muse, mutect2, varscan2
- CLCA1 | c.1318T>G p.S440A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV52325914; called by muse, mutect2, varscan2
- CNST | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 97/310 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV63620035; called by muse, mutect2, varscan2
- CTTNBP2 | c.4585G>T p.D1529Y | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50391965; called by muse, mutect2, varscan2
- CYC1 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59644043; called by muse, mutect2, varscan2
- DKKL1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55561834; called by muse, mutect2, varscan2
- DNAH10 | c.13370T>C p.I4457T (on ENST00000409039; = p.I4396T on NM_207437.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs758629154, COSV99435898; called by muse, varscan2
- DRP2 | c.1826A>G p.K609R | Missense Mutation (SNP) | VAF 114/122 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65809593; called by muse, varscan2
- EDA | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65780213; called by muse, mutect2, varscan2
- EPC1 | c.613A>C p.N205H | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV53923933; called by muse, mutect2, varscan2
- ESYT1 | c.2287T>A p.L763M | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57271976; called by muse, mutect2, varscan2
- ETV3L | c.606C>T p.Y202= | Splice Region (SNP) | VAF 43/106 reads (41%) | catalogued as COSV71901003; called by muse, mutect2, varscan2
- FAM131B | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.961); catalogued as COSV58368329; called by muse, mutect2, varscan2
- FAM13A | c.1938G>A p.M646I | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.027); catalogued as COSV51999087; called by muse, mutect2, varscan2
- FST | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV56815126; called by muse, mutect2, varscan2
- GCDH | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV53365991; called by muse, mutect2, varscan2
- GPC5 | c.279C>A p.S93R | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65584965; called by muse, mutect2, varscan2
- GPR55 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV101235924; called by muse, mutect2, varscan2
- GPR55 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV101235925; called by muse, mutect2, varscan2
- HTR5A | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as rs774888130, COSV55281395; called by muse, mutect2, varscan2
- JCAD | c.1617A>T p.R539S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1243115272, COSV100948559, COSV64758242; called by muse, mutect2, varscan2
- JCAD | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100948560; called by muse, mutect2, varscan2
- KCNA6 | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV54974457; called by muse, mutect2, varscan2
- KIAA0319 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 68/223 reads (30%) | catalogued as COSV100985682, COSV65497046; called by muse, mutect2, varscan2
- KIF16B | c.3331G>T p.V1111F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.054); catalogued as rs746936982, COSV61702925; called by muse, mutect2, varscan2
- KRBOX4 | c.336G>C p.K112N (on ENST00000344302 / NM_001129898.2; = p.K107N on NM_017776.2) | Missense Mutation (SNP) | VAF 65/71 reads (92%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV53343002; called by muse, mutect2, varscan2
- KRT85 | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57736267; called by muse, mutect2, varscan2
- LLGL2 | c.2111C>G p.S704W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754925688, COSV51344107; called by muse, mutect2, varscan2
- LPCAT1 | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV52036205; called by muse, mutect2, varscan2
- LRCH2 | c.614T>G p.M205R | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57747553; called by muse, mutect2, varscan2
- MAGEE1 | c.879C>A p.S293R | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV63909057, COSV63909254; called by muse, mutect2, varscan2
- MFGE8 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51555533; called by muse, mutect2, varscan2
- MKNK1 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57860692; called by muse, mutect2, varscan2
- MYH1 | c.3001A>G p.K1001E | Missense Mutation (SNP) | VAF 126/240 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV56845188; called by mutect2, varscan2
- MYH13 | c.640A>C p.M214L | Missense Mutation (SNP) | VAF 96/100 reads (96%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52822878; called by mutect2, varscan2
- MYH9 | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV53383381; called by muse, mutect2, varscan2
- MYO1B | c.2539T>A p.Y847N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV58428641; called by muse, mutect2, varscan2
- NAV3 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57067787; called by muse, mutect2, varscan2
- NIPBL | c.8378G>A p.R2793Q | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as rs1375623038, COSV56945750; called by muse, mutect2, varscan2
- NPY5R | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs775716946, COSV58451324; called by muse, mutect2, varscan2
- NRP2 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs754078889, COSV99785625; called by muse, mutect2
- NUMA1 | c.3985T>G p.L1329V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.391); catalogued as COSV100706593; called by muse, mutect2
- OR4E2 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57731497; called by muse, varscan2
- OR4E2 | c.748T>A p.F250I | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV57731502; called by muse, varscan2
- PCDHGA4 | c.1348A>T p.N450Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV53915274; called by muse, mutect2, varscan2
- PCDHGB6 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.219); catalogued as COSV53915283; called by muse, mutect2, varscan2
- PDPN | c.4T>A p.W2R (on ENST00000621990; = p.W78R on NM_006474.4) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53846884; called by muse, mutect2, varscan2
- PHIP | c.3788A>T p.Q1263L | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51502367; called by muse, mutect2, varscan2
- PPP1R3A | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52875057, COSV52878643; called by muse, mutect2, varscan2
- PRRC2A | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs760996116, COSV65685669; called by muse, varscan2
- PTPRZ1 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 101/422 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV66432645; called by muse, mutect2, varscan2
- RYR2 | c.5833A>T p.N1945Y | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.898); catalogued as COSV63671113; called by muse, mutect2, varscan2
- SH3GLB1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV65279357; called by muse, mutect2, varscan2
- SLC12A2 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772690122, COSV52469337; called by muse, mutect2, varscan2
- SLC28A1 | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54477411; called by muse, mutect2, varscan2
- SPPL2A | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55940271; called by muse, mutect2, varscan2
- THSD1 | c.1481T>A p.I494N | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51627209; called by muse, mutect2, varscan2
- TMEM263 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV55013728; called by muse, mutect2, varscan2
- TNFSF18 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV53439986; called by muse, mutect2, varscan2
- TOMM7 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV100626999; called by muse, mutect2
- TP53 | c.574del p.Q192Sfs*55 | Frame Shift Del (DEL) | VAF 75/78 reads (96%) | catalogued as COSV52660737, COSV52978302; called by mutect2, varscan2
- TRRAP | c.7637C>G p.P2546R (on ENST00000359863 / NM_001244580.1; = p.P2528R on NM_003496.3) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV62841089; called by muse, mutect2, varscan2
- UNC5D | c.1526C>A p.T509N | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV54777610; called by muse, mutect2, varscan2
- VPS13C | c.6805C>G p.H2269D (on ENST00000644861 / NM_020821.3; = p.H2226D on NM_017684.5) | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs372868009; called by muse, mutect2, varscan2
- VRK3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV57464998; called by muse, mutect2, varscan2
- WDR31 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV59145635; called by muse, mutect2, varscan2
- ZNF383 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV61938716; called by muse, mutect2, varscan2
- ARID1A | c.3216dup p.W1073Mfs*32 | Frame Shift Ins (INS) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- FXR1 | c.1231dup p.T411Nfs*4 | Frame Shift Ins (INS) | VAF 44/218 reads (20%) | called by mutect2, pindel, varscan2
- HGH1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- IFIT1B | c.755_779del p.Y252Ffs*15 | Frame Shift Del (DEL) | VAF 128/390 reads (33%) | called by mutect2, varscan2
- MRTFB | c.1213-3_1218del p.X405_splice | Splice Site (DEL) | VAF 38/88 reads (43%) | called by mutect2, varscan2
- RNF213 | c.15170del p.G5057Vfs*8 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.693del p.F233Lfs*8 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, varscan2
- STX1B | c.278_280+5del p.X93_splice | Splice Site (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- ADGRV1 | c.1734A>T p.S578= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV67980621; called by muse, mutect2, varscan2
- ARHGAP26 | c.513G>A p.R171= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs1420872629, COSV50825613; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1830C>A p.P610= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as COSV100023674; called by muse, mutect2
- CCDC88B | c.192G>T p.R64= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV57265326; called by muse, mutect2, varscan2
- CNGA4 | c.1461C>T p.I487= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs376820772; called by muse, mutect2, varscan2
- EPSTI1 | c.903C>T p.L301= (on ENST00000398762 / NM_001330543.2; = p.L290= on NM_033255.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/139 reads (48%) | catalogued as rs774966421, COSV58044473; called by muse, mutect2, varscan2
- FAT4 | c.2982A>G p.P994= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as COSV67882750; called by muse, mutect2, varscan2
- FLRT3 | c.852T>C p.S284= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as COSV53958206; called by muse, mutect2, varscan2
- GALNT15 | c.1578C>A p.I526= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as COSV60215898; called by muse, mutect2, varscan2
- GBP6 | c.759A>T p.S253= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV65010956; called by muse, mutect2, varscan2
- HLA-DPA1 | c.558C>G p.P186= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV70088486; called by muse, mutect2, varscan2
- HSF2BP | c.501G>A p.S167= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as rs780045050, COSV52355047; called by muse, mutect2, varscan2
- ITIH1 | c.63C>T p.I21= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV56253198; called by muse, mutect2, varscan2
- KIAA1614 | c.288G>T p.V96= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV62552479; called by muse, mutect2, varscan2
- LDHC | c.889C>A p.R297= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV55003622; called by muse, mutect2, varscan2
- MBD5 | c.4302G>A p.L1434= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV68696193; called by muse, mutect2, varscan2
- MUC5B | c.5685C>G p.A1895= | Silent (SNP) | VAF 34/36 reads (94%) | catalogued as COSV71590574; called by muse, mutect2, varscan2
- NEDD4L | c.384T>C p.F128= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV56842053; called by muse, mutect2, varscan2
- NICN1 | c.276A>T p.G92= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV56469157; called by muse, mutect2, varscan2
- NUP155 | c.1689A>G p.R563= (on ENST00000231498 / NM_153485.3; = p.R504= on NM_004298.4) | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV51528059; called by muse, mutect2, varscan2
- OGN | c.330C>T p.D110= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as COSV52760493; called by muse, mutect2, varscan2
- OR2T27 | c.300A>G p.Q100= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV100788399; called by mutect2, varscan2
- PPP1R7 | c.654C>T p.N218= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as COSV52143925; called by muse, mutect2, varscan2
- PXN | c.21G>T p.L7= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV57217712; called by muse, mutect2, varscan2
- RALGDS | c.1755G>C p.L585= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV64426089; called by muse, mutect2, varscan2
- RAMP3 | c.93A>T p.T31= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV54245024; called by muse, mutect2, varscan2
- RFX5 | c.1113C>T p.A371= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs377016578; called by muse, mutect2, varscan2
- RP2 | c.861C>T p.D287= | Silent (SNP) | VAF 35/39 reads (90%) | catalogued as COSV54461176; called by muse, mutect2, varscan2
- SLC14A2 | c.1116C>T p.A372= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs1392211239, COSV54907254; called by muse, mutect2, varscan2
- SLX4 | c.4227C>G p.A1409= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs1183410287, COSV53562195; called by muse, mutect2, varscan2
- TCAF1 | c.363C>A p.S121= | Silent (SNP) | VAF 62/277 reads (22%) | catalogued as COSV63517795; called by muse, mutect2, varscan2
- TCL1A | c.195C>A p.T65= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV68085232; called by muse, mutect2, varscan2
- TGM6 | c.732C>T p.G244= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs200686759, COSV52478133; called by muse, mutect2, varscan2
- TTC12 | c.1239G>T p.L413= | Silent (SNP) | VAF 34/36 reads (94%) | catalogued as COSV59097068; called by muse, mutect2, varscan2
- FAM135A | c.823+4067G>A | Intron (SNP) | VAF 20/21 reads (95%) | catalogued as rs369691884; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559152 G>A | 5'Flank (SNP) | VAF 75/198 reads (38%) | catalogued as rs1365827185; called by muse, mutect2, varscan2
